Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5KZ, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5KZ-01A (Primary Tumor).

Procedure: adrenalectomy

Gross description: 14 x 9 x 5cm, 336g

Reference Pathology only:

Diagnosis: adrenocortical carcinoma, with unusually high proliferation rate, KI67 60%

Weiss score: 8

Hough score: 4.89

Van Slooten score: 22.7

ICD-O-3
Carcinoma, adrenal cortical
8370/3
Site: Adrenal Gland Cortex
C74.0
JED 2/6/13

Source: NCI Genomic Data Commons file f144a01b-f878-4906-9478-0849e5ee0316 (TCGA-OR-A5KZ.22298C81-A72D-4E22-99DD-6541FB0953A4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).